Somatic mutation profile of tumor specimen TCGA-OR-A5K3-01A (aliquot TCGA-OR-A5K3-01A-11D-A29I-10) from TCGA case TCGA-OR-A5K3, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 53.0 years (19,375 days).
Specimen TCGA-OR-A5K3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5e586ef-45f6-473e-906a-2085c3d51a94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5K3-10A (Blood Derived Normal), aliquot TCGA-OR-A5K3-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2881db95-b8c6-4d15-a6b5-234cca1f3be8

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 2, In Frame Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2A2 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs746309999; called by muse, mutect2, varscan2
- ESPN | c.343G>C p.G115R | Missense Mutation (SNP) | VAF 147/174 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs765867875; called by muse, mutect2, varscan2
- EYA1 | c.1684C>G p.Q562E | Missense Mutation (SNP) | VAF 82/105 reads (78%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.907); catalogued as rs1481254965, COSV58161752; called by muse, mutect2, varscan2
- FBN2 | c.6320A>C p.N2107T | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as rs183350360; called by muse, mutect2, varscan2
- LAMC3 | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 61/75 reads (81%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1040314137; called by muse, mutect2, varscan2
- PLXNC1 | c.2459C>T p.T820M | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs770962418, COSV99314174; called by muse, mutect2, varscan2
- TRIM22 | c.1208C>G p.P403R | Missense Mutation (SNP) | VAF 53/65 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173249948; called by muse, mutect2, varscan2
- TUT7 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as rs142251867; called by muse, varscan2
- FCHO1 | c.607A>G p.M203V | Missense Mutation (SNP) | VAF 156/328 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLT4 | c.3841T>C p.S1281P | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- GARS1 | c.719A>G p.E240G | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- HSDL1 | c.222T>A p.G74= | Splice Region (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- PLPBP | c.581C>A p.P194Q | Missense Mutation (SNP) | VAF 85/101 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- SIX4 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); called by muse, varscan2
- TM2D3 | c.12_29del p.V5_G10del | In Frame Del (DEL) | VAF 32/61 reads (52%) | called by mutect2, varscan2
- AKR1D1 | c.57C>A p.P19= | Silent (SNP) | VAF 16/239 reads (7%) | called by muse, mutect2
- OR13C8 | c.258G>T p.L86= | Silent (SNP) | VAF 29/89 reads (33%) | called by muse, mutect2, varscan2
- KMT5C | c.570+645G>T | Intron (SNP) | VAF 74/181 reads (41%) | catalogued as rs1334158717; called by muse, mutect2, varscan2
